Gene-level copy-number profile of tumor specimen TCGA-B6-A0IJ-01A from TCGA case TCGA-B6-A0IJ, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 42.8 years (15,625 days).
Specimen TCGA-B6-A0IJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.6c71c171-be2a-4eac-bae9-841c1192ab61.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B6-A0IJ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/91d5adf4-7f10-48d5-8607-3afc225c4ada

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 131; copy number 1: 1,347; copy number 2: 22,784; copy number 3: 15,770; copy number 4: 12,131; copy number 5: 2,956; copy number 6: 2,786; copy number 7: 1,294; copy number 8: 280; copy number 9: 314; copy number 10: 22; copy number 13: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-B6-A0IJ-01A-11D-A036-01): tumor purity 0.4, ploidy 3.22, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 131 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:186,266,189–190,092,279, 74 genes (broad region; genes not listed).
- chr5:161,288,429–166,382,599, 37 genes: GABRB2, GABRA6, AC091944.1, GLRXP3, GABRA1, LINC01202, GABRG2, AC113414.1, RNU6-164P, ARL2BPP5, MRPL57P6, AC008723.1, CCNG1, NUDCD2, HMMR, HMMR-AS1, MAT2B, AC010291.1, AC116917.1, RNU6-168P, AC008432.1, LSM1P2, AC008662.1, AC008662.2, AC109466.1, LINC02143, AC008446.1, RNU6-209P, AC091973.1, LINC01938, AC008415.1, RN7SKP60, AC008562.1, AC008489.1, RPL7P20, AC114321.1, AC026403.1.
- chr5:167,937,717–168,472,303, 7 genes (within-gene range 0–3): AC008464.1, AC008705.2, AC008705.1, AC011369.1, AC011369.2, CTB-178M22.2, WWC1.
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–1): MTAP, AL359922.1.
- chr9:21,858,910–22,128,103, 11 genes: AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7,653 genes in 43 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:43,447,776–44,788,170, 56 genes, copy number 9: SZT2-AS1, MIR6735, HYI, HYI-AS1, PTPRF, KDM4A, AL451062.2, KDM4A-AS1, ST3GAL3, ST3GAL3-AS1, U6, AL451062.1, MIR6079, SHMT1P1, ARTN, AL357079.1, AL357079.3, IPO13, AL357079.2, DPH2, ATP6V0B, B4GALT2, CCDC24, SLC6A9, AL139220.2, AL139220.1, KRT8P47, RN7SL479P, KLF17, AL356653.1, KLF18, AL359839.1, Y_RNA, OOSP1P1, AL035417.1, AL035417.2, DMAP1, ERI3, ERI3-IT1, RNU6-369P, RNF220, MIR5584, TMEM53, ARMH1, RNU5F-1, RNU5D-1, KIF2C, AL592166.1, RPS8, SNORD55, SNORD46, SNORD38A, SNORD38B, SNORD38B, RPS15AP11, BEST4.
- chr1:47,760,528–47,997,385, 1 gene, copy number 6 (within-gene range 2–6): TRABD2B.
- chr1:48,050,659–66,374,579, 356 genes, copy number 5–7 (within-gene range 5–8) (broad region; genes not listed).
- chr1:75,724,347–91,906,335, 240 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr1:143,343,180–232,223,145, 2,220 genes, copy number 6–8 (broad region; genes not listed).
- chr2:38,193,348–38,929,072, 23 genes, copy number 6 (within-gene range 4–6): AC009229.3, AC009229.1, RPL7P12, GAPDHP25, ATL2, LINC02613, AC016995.1, LINC01883, RPLP0P6, AC011247.2, HNRNPLL, AC011247.1, GALM, AC074366.1, SRSF7, GEMIN6, TTC39DP, NPLP1, DHX57, ASS1P2, AC018693.1, MORN2, RNU6-851P.
- chr2:160,849,313–165,794,659, 56 genes, copy number 5–6 (within-gene range 4–6): AC096656.1, RN7SL423P, AC009313.1, TANK-AS1, TANK, AC009299.2, LINC01806, AC009299.1, PSMD14, MXRA7P1, RNA5SP108, TBR1, AC009487.1, AC009487.2, SLC4A10, AC009487.3, AHCTF1P1, AC092654.1, AC062022.1, AC062022.2, KRT18P46, RPEP5, DPP4, DPP4-DT, TIMM8AP1, EIF3EP2, AC008063.1, GCG, AC007750.1, FAP, IFIH1, GCA, KCNH7, RNA5SP109, KCNH7-AS1, RPL7P61, RNU6-627P, FIGN, AC016766.1, PRPS1P1, CYP2C56P, GRB14, AC107075.1, COBLL1, AC019181.1, SNORA70F, AC019197.1, RNA5SP110, RNA5SP111, SLC38A11, SCN3A, SCN2A, MAPRE1P3, AC011303.1, CSRNP3, GALNT3.
- chr2:202,874,261–203,636,016, 17 genes, copy number 6 (within-gene range 4–6): WDR12, CARF, KRT8P52, AC010900.1, NBEAL1, RPL7P14, AC023271.1, AC023271.2, RPL23AP36, RPL12P16, CYP20A1, RN7SL670P, MRPL50P2, ABI2, AC080075.1, RAPH1, AC125238.2.
- chr3:857,124–4,985,323, 36 genes, copy number 5: AC090044.1, AC087430.1, RN7SL120P, CNTN6, CRB3P1, RPL23AP38, RPL23AP39, RPL21P17, AC018814.1, RN7SKP144, CNTN4, CNTN4-AS2, AC087427.1, HINT2P1, DNAJC19P4, CNTN4-AS1, IL5RA, AC024060.1, TRNT1, CRBN, AC024060.2, AC034195.1, SUMF1, LRRN1, AC023480.1, PNPT1P1, AC023483.1, SETMAR, MRPS10P2, ITPR1-DT, ITPR1, EGOT, AC018816.2, AC018816.1, BHLHE40-AS1, BHLHE40.
- chr5:4,012,708–32,110,932, 389 genes, copy number 6–7 (within-gene range 3–7) (broad region; genes not listed).
- chr5:32,174,471–38,671,216, 116 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr6:37,482,938–63,779,336, 434 genes, copy number 5–7 (broad region; genes not listed).
- chr6:63,797,189–63,857,769, 3 genes, copy number 5: AL354719.1, SCAT8, GCNT1P4.
- chr6:66,710,242–70,351,802, 27 genes, copy number 5–13: AL450336.1, RNU7-66P, AL591004.1, AL365503.1, RNA5SP208, RNU6-280P, Y_RNA, AL713998.1, AL713998.3, AL713998.4, AL713998.2, AL646090.2, AL646090.1, AL593844.1, LINC02549, AL606923.2, AL606923.1, AL391807.1, ADGRB3, LMBRD1, NPM1P37, GAPDHP42, COL19A1, RPL37P15, COL9A1, AL160262.1, AL080275.1.
- chr8:46,870,902–49,229,174, 49 genes, copy number 6: AC091163.3, AC091163.1, AC091163.2, MAPK6P4, RN7SKP32, AC120036.1, AC120036.5, RNU6-819P, RPL10AP2, NDUFA5P12, AC120036.3, AC120036.4, ATP6V1G1P2, AC120036.2, IGLV8OR8-1, SPIDR, AC024451.2, AC024451.4, AC024451.1, AC024451.3, RNU6-665P, CEBPD, PRKDC, Y_RNA, AC021236.1, MCM4, RNU6-519P, UBE2V2, AC104989.1, IDI1P2, RNU6-295P, RNA5SP531, RPL29P19, AC041040.1, AC026904.1, AC026904.2, AC022915.2, LINC02599, LINC02847, AC022915.1, AC022915.3, EFCAB1, AC100805.1, AC013701.1, SNAI2, AC013701.2, AC044893.2, PPDPFL, AC044893.1.
- chr8:89,585,872–90,053,633, 8 genes, copy number 5 (within-gene range 3–5): AF117829.1, RIPK2, COX6B1P6, AF117829.2, RNU6-925P, OSGIN2, NBN, DECR1.
- chr8:90,621,995–91,044,762, 9 genes, copy number 5: TMEM64, AC106038.1, AC106038.2, NECAB1, AC103770.1, C8orf88, PIP4P2, AC087439.1, AC087439.2.
- chr8:94,352,923–104,256,094, 220 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr8:108,162,787–145,066,685, 558 genes, copy number 5–9 (within-gene range 1–9) (broad region; genes not listed).
- chr9:14,475–3,053,408, 45 genes, copy number 6–8: WASHC1, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1, AL158832.2, DOCK8-AS1, DOCK8, AL158832.1, AL161725.1, KANK1, RPL12P25, AL161725.2, AL392089.1, RNU6-1327P, EIF1P1, AL136979.1, DMRT1, DMRT3, RNU6-1073P, H3P29, AL358976.1, LINC01230, DMRT2, AL356498.1, RPS27AP14, AL358934.1, RNA5SP279, AL358053.1, AL591644.1, SMARCA2, AL359076.1, RNU2-25P, RN7SL592P, VLDLR-AS1, AL353614.1, VLDLR, AL450467.1, KCNV2, PUM3, GPS2P1, ATP5PDP2, CARM1P1.
- chr9:12,685,439–14,069,417, 19 genes, copy number 7: TYRP1, LURAP1L-AS1, RN7SL849P, LURAP1L, Y_RNA, AL161449.2, PRDX1P1, AL161449.1, MPDZ, AL162386.2, AL162386.1, AL583785.1, LINC01235, AL158157.1, LINC00583, PES1P2, AL360089.1, RPL3P11, ATP5PDP3.
- chr9:68,426,843–90,752,230, 300 genes, copy number 5–7 (broad region; genes not listed).
- chr10:44,712–5,566,881, 104 genes, copy number 6–9 (broad region; genes not listed).
- chr10:42,279,734–55,746,908, 270 genes, copy number 5 (broad region; genes not listed).
- chr10:58,334,979–67,696,195, 80 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).
- chr10:67,750,284–70,019,496, 74 genes, copy number 5 (broad region; genes not listed).
- chr10:120,608,580–133,761,125, 235 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr11:72,249,856–72,793,681, 26 genes, copy number 5: AP000593.2, AP000593.4, AP000593.1, CLPB, AP000593.3, AP002892.2, AP002892.1, AP003785.1, ART2BP, ART2P, AP005019.2, AP005019.1, LINC01537, PDE2A, PDE2A-AS2, MIR139, RNU7-105P, PDE2A-AS1, ARAP1, ARAP1-AS1, AP003065.1, ARAP1-AS2, RPS12P20, STARD10, Y_RNA, MIR4692.
- chr11:82,899,975–86,423,109, 60 genes, copy number 5 (within-gene range 2–5): DDIAS, AP000893.1, AP000893.2, RAB30, AP001767.1, SNORA70E, RAB30-DT, AP001767.2, AP001767.3, COX5BP4, C1DP5, BCAS2P1, PCF11, AP000873.4, AP000873.2, PCF11-AS1, ANKRD42, CKS1BP4, AP000873.3, AP000873.1, CCDC90B, AP000446.1, CYCSP28, AP000446.2, DLG2, DLG2-AS2, AP002370.1, LDHAL6DP, HNRNPA1P72, AP000852.1, AP001825.1, AP001825.2, AP001825.3, AP000857.2, AP000857.1, HNRNPCP6, AP002803.1, AP003035.1, RNU6-1292P, TMEM126B, TMEM126A, CREBZF, CCDC89, SYTL2, AP000974.1, CCDC83, AP003128.1, SLC25A1P1, PICALM, RNU6-560P, LINC02695, FNTAP1, Metazoa_SRP, EED, MIR6755, AP003084.1, SETP17, HIKESHI, RN7SL225P, CCDC81.
- chr12:7,470,811–11,895,377, 213 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr12:12,111,163–12,112,036, 2 genes, copy number 6: PTMAP9, MIR1244-4.
- chr12:68,674,371–69,855,363, 35 genes, copy number 6–9 (within-gene range 2–9): AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2.
- chr16:75,838,576–79,212,667, 47 genes, copy number 5 (within-gene range 3–5): AC105430.1, RNA5SP430, AC099511.1, AC010528.1, RPL18P13, AC010528.2, CNTNAP4, AC106741.1, RN7SKP233, SNORD33, AC108125.1, LINC02125, AC106729.1, MIR4719, AC106734.1, AC106733.1, MON1B, SYCE1L, AC009139.2, VN2R10P, AC009139.1, ADAMTS18, AC025284.1, LINC02131, AC092724.1, NUDT7, AC092134.1, AC092134.3, VAT1L, AC092134.2, PPIAP50, AC079414.1, CLEC3A, KRT8P22, AC079414.2, WWOX, AC079414.3, AC009044.1, WWOX-AS1, AC106743.1, LSM3P5, AC046158.1, AC046158.4, AC046158.2, AC046158.3, AC009141.1, RPS3P7.
- chr16:79,090,050–90,222,851, 316 genes, copy number 5 (broad region; genes not listed).
- chr17:70,166,961–70,629,265, 5 genes, copy number 9: KCNJ2-AS1, KCNJ2, CALM2P1, AC011990.1, AC005771.1.
- chr19:27,638,483–29,564,479, 46 genes, copy number 5: ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B.
- chr19:43,690,002–45,305,284, 89 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr20:30,323,367–55,684,915, 634 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr21:15,614,283–22,884,000, 85 genes, copy number 5–10 (broad region; genes not listed).
- chr22:36,388,626–39,437,060, 147 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,345. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
